Gene-level copy-number profile of tumor specimen ALCH-AEBR-TTR1-A from ALCHEMIST case ALCH-AEBR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.0 years (23,734 days).
Specimen ALCH-AEBR-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6e711b3e-7db1-4007-9bf1-9163b00d1cd7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEBR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,250 have no estimate.
https://portal.gdc.cancer.gov/files/de9b0b27-dc07-4cd2-ae83-0a35f65f3405

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,244; copy number 2: 11,048; copy number 3: 15,745; copy number 4: 16,634; copy number 5: 5,452; copy number 6: 2,419; copy number 7: 1,131; copy number 8: 2,320; copy number 9: 214; copy number 10: 78; copy number 11: 36; copy number 12: 983; copy number 13: 15; copy number 14: 28; copy number 15: 7; copy number 16: 16; copy number 18: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,378 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:101,802,560–101,996,926, 1 gene, copy number 9 (within-gene range 4–9): OLFM3.
- chr1:101,882,516–103,108,872, 6 genes, copy number 9: AL356280.1, DNAJA1P5, AC114485.1, AC099567.1, COL11A1, SOD2P1.
- chr1:104,072,983–104,226,678, 2 genes, copy number 9: AC092506.1, FTLP17.
- chr1:118,614,333–120,842,110, 53 genes, copy number 9–10: PSMC1P12, AL139148.1, TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26.
- chr1:143,419,625–169,132,722, 979 genes, copy number 12–15 (within-gene range 8–15) (broad region; genes not listed).
- chr8:66,363,774–67,746,378, 32 genes, copy number 10 (within-gene range 8–10): AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10.
- chr8:67,952,046–68,819,023, 9 genes, copy number 9–13: PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269.
- chr8:69,834,111–75,566,834, 104 genes, copy number 9–18 (within-gene range 8–18) (broad region; genes not listed).
- chr8:76,681,239–77,537,290, 7 genes, copy number 9 (within-gene range 7–9): ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1.
- chr8:79,611,117–81,284,777, 45 genes, copy number 11–14: STMN2, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5.
- chr16:11,555–1,612,072, 140 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 777. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
